Somatic mutation profile of tumor specimen 0DGRHM from CCDI case PBBTVS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,232 days).
Specimen 0DGRHM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7aecb8ef-4430-40d3-b6d0-946177870914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGRHU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/919180c5-3377-4611-94f8-db3845654c89

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 616/1647 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754176932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.3877C>T p.Q1293* | Nonsense Mutation (SNP) | VAF 743/1992 reads (37%) | called by muse, mutect2, varscan2
- GNL2 | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 90/1305 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); called by muse, mutect2
- APC2 | c.6279G>A p.P2093= | Silent (SNP) | VAF 40/440 reads (9%) | catalogued as rs1450284278; called by muse, mutect2
- NPHS1 | c.966C>T p.S322= | Silent (SNP) | VAF 263/654 reads (40%) | catalogued as rs747512201; called by muse, mutect2, varscan2
- ZXDA | c.1977G>A p.P659= | Silent (SNP) | VAF 191/1991 reads (10%) | catalogued as rs756856912; called by muse, varscan2
- LIMCH1 | c.936-5383G>A | Intron (SNP) | VAF 336/718 reads (47%) | catalogued as rs961109709; called by muse, mutect2, varscan2
- WBP4 | c.-25G>A | 5'UTR (SNP) | VAF 369/922 reads (40%) | catalogued as COSV101069220; called by muse, mutect2, varscan2
